Somatic mutation profile of tumor specimen 0DT3UC from CCDI case PBCIRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 9.7 years (3,542 days).
Specimen 0DT3UC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa42b22c-af4d-4c19-b167-abc09bd8151d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3UR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27a76476-2748-4f1e-9769-71b458fc82e1

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSG8 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 34/1127 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs1247193012; called by muse, mutect2
- UNC13A | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 41/666 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1159927210; called by muse, mutect2
- YY2 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 58/1392 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV63410894; called by muse, mutect2
- FUBP3 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- PAK2 | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 58/1460 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2
- CCDC85A | c.1596T>C p.D532= | Silent (SNP) | VAF 36/1452 reads (2%) | called by muse, mutect2
- HCN1 | c.135C>A p.G45= | Silent (SNP) | VAF 26/466 reads (6%) | called by muse, mutect2
- PDK1 | c.1053T>A p.P351= | Silent (SNP) | VAF 37/1135 reads (3%) | called by muse, mutect2
- STRAP | c.897G>A p.T299= | Silent (SNP) | VAF 72/1214 reads (6%) | catalogued as rs140559082, COSV50309195; called by muse, mutect2
